CCDI case PBCLLK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/769ea1f7-594f-4586-87ba-b7005d4e79bc

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.2 years (426 days).

Biospecimens (3 samples)
- Sample 0DUKGW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKHD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUKIY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
